Somatic mutation profile of tumor specimen TCGA-CV-7236-01A (aliquot TCGA-CV-7236-01A-11D-2012-08) from TCGA case TCGA-CV-7236, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 77.3 years (28,250 days).
Specimen TCGA-CV-7236-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 571f5a01-e8fb-4a5d-a378-96428560be52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7236-10A (Blood Derived Normal), aliquot TCGA-CV-7236-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eb2ffc4-bc86-45f4-8a75-bd288249e1d9

The open-access MAF lists 48 somatic variants for this specimen: 27 protein-altering or splice-affecting, 21 silent.
By variant classification: Missense Mutation 21, Silent 21, In Frame Del 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.3157C>T p.R1053W | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730880903, COSV100806383; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NOTCH1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1057523819, COSV53030190; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 11/64 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587782620, CM132087, COSV52665025, COSV53025766, COSV53135444, COSV53176166; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNMT3B | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.406); catalogued as COSV52420100, COSV99142675; called by muse, mutect2, varscan2
- ENPEP | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as rs201187378, COSV54450662, COSV99487494; called by muse, mutect2, varscan2
- EVX2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as rs1352208314, COSV57962376; called by muse, mutect2
- FGD5 | c.3239G>A p.R1080H | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.57); PolyPhen benign (0.062); catalogued as rs375051384; called by muse, mutect2, varscan2
- FSHB | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99569276; called by muse, mutect2
- GRIN2C | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs774105712, COSV99501249; called by muse, mutect2, varscan2
- H2BC12 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV63616941; called by muse, mutect2
- HNF4G | c.746-1G>A p.X249_splice (on ENST00000354370 / NM_001330561.2; = p.X296_splice on NM_004133.5) | Splice Site (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100584815; called by muse, mutect2, varscan2
- MUC5B | c.4780C>T p.R1594W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1022208427, COSV101500290; called by muse, mutect2
- OR1S1 | c.552C>A p.H184Q | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs201200340, COSV100515459; called by muse, mutect2, varscan2
- P2RY10 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99409246; called by muse, mutect2, varscan2
- PLEC | c.10645G>A p.A3549T (on ENST00000322810 / NM_201380.4; = p.A3439T on NM_000445.5) | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1259520719, COSV100516817; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCH | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1375857040, COSV100273570; called by muse, mutect2, varscan2
- RAPGEF1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1266562115, COSV64699509; called by muse, mutect2, varscan2
- SLCO5A1 | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs772735964, COSV99480566; called by muse, mutect2, varscan2
- TTN | c.89711G>A p.R29904H (on ENST00000591111; = p.R22480H on NM_003319.4) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | PolyPhen probably damaging (0.982); catalogued as rs920039018, COSV59902824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USH2A | c.13483C>T p.R4495C | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs746221227, CM1410608, COSV56332428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WDR49 | c.1624A>T p.K542* (on ENST00000308378 / NM_001366158.1; = p.K883* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV100393436; called by muse, mutect2, varscan2
- XDH | c.2190_2192del p.V731del | In Frame Del (DEL) | VAF 22/170 reads (13%) | catalogued as rs760761330; called by pindel, varscan2
- ZMYND8 | c.3512C>T p.T1171M (on ENST00000311275 / NM_001363741.2; = p.T1145M on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as rs1347712043, COSV53698417, COSV99519573; called by muse, mutect2, varscan2
- ZNF215 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99549804; called by muse, mutect2
- ZNF777 | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs201615239, COSV56098499; called by muse, mutect2, varscan2
- UBE2J2 | c.477_478del p.L159Ffs*3 | Frame Shift Del (DEL) | VAF 14/110 reads (13%) | called by mutect2, pindel, varscan2
- WNK3 | c.4565_4567del p.S1522_D1523delinsN | In Frame Del (DEL) | VAF 28/247 reads (11%) | called by mutect2, pindel, varscan2
- ABCD4 | c.1281G>A p.K427= | Silent (SNP) | VAF 27/161 reads (17%) | catalogued as COSV100084432; called by muse, mutect2, varscan2
- ABHD2 | c.525C>T p.R175= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs769872239, COSV100756402; called by muse, mutect2, varscan2
- ATG2B | c.18G>C p.S6= | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100738140; called by muse, mutect2, varscan2
- BEST2 | c.765C>T p.R255= | Silent (SNP) | VAF 17/114 reads (15%) | catalogued as COSV99244570; called by muse, mutect2, varscan2
- CHL1 | c.288C>T p.N96= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs777628797, COSV56607984, COSV99851799; called by muse, mutect2, varscan2
- DNAAF3 | c.1371C>T p.S457= (on ENST00000524407 / NM_001256715.2; = p.S504= on NM_178837.4) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV100787965; called by muse, mutect2, varscan2
- DST | c.7299G>A p.L2433= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV55041132; called by muse, mutect2, varscan2
- GOLGA2 | c.2542C>A p.R848= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as rs1007495705, COSV100360176; called by muse, mutect2
- GPC5 | c.906C>T p.L302= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV100995038; called by muse, mutect2, varscan2
- HAND2 | c.522C>T p.T174= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs1324334184, COSV100854220, COSV64017999; called by mutect2, varscan2
- HIC2 | c.714C>T p.S238= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs1404200612, COSV101335604; called by muse, mutect2, varscan2
- KNL1 | c.6952C>T p.L2318= (on ENST00000346991 / NM_170589.5; = p.L2292= on NM_144508.5) | Silent (SNP) | VAF 19/109 reads (17%) | catalogued as COSV100706783; called by muse, mutect2, varscan2
- LRRC75B | c.621G>A p.L207= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs111248278; called by muse, mutect2, varscan2
- MEGF8 | c.1524G>A p.A508= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs748837091, COSV52102889; called by mutect2, varscan2
- MYH14 | c.5481C>T p.A1827= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99223533; called by muse, mutect2, varscan2
- NETO1 | c.150A>G p.G50= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100199270; called by muse, mutect2
- NUP58 | c.54C>T p.A18= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV101098855; called by muse, mutect2
- PLCE1 | c.3438C>A p.S1146= | Silent (SNP) | VAF 24/241 reads (10%) | catalogued as COSV99596229; called by muse, mutect2
- RAPGEF2 | c.858G>A p.E286= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs780673052, COSV100031446; called by muse, mutect2, varscan2
- ZNF510 | c.1689G>A p.Q563= | Silent (SNP) | VAF 9/137 reads (7%) | catalogued as COSV99793924; called by muse, mutect2
- ZNF775 | c.1353C>T p.C451= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV61613837; called by muse, mutect2, varscan2
